Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A17X, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A17X-06A (Metastatic).

[page 1 of 2]
12/19/10
h

ICD-0-3

Melanoma, NOS 8720/3

Site Code: Axilla, NOS C44.5

DOB/Age/Sex:

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

Copies to:

years Male

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Recurrent melanoma cheek. Enlarged right axillary nodes. Reassessment of lesion. (R) axillary lymph node assessment.

(R) axillary dissection specimen. (R) anterior abdominal wall lesion.

MACROSCOPIC DESCRIPTION

Two specimens were received.

1. "RIGHT AXILLARY DISSECTION". Tissue received fresh for melanoma tumour banking. Tissue taken: lymph node with metastatic melanoma. B,

An unorientated piece of fibrofatty tissue 130 x 100 x 40mm, with attached skeletal muscle 85 x 60 x 20mm. Multiple enlarged lymph nodes were identified (from 6 - 30mm across), many of which were macroscopically involved, and appeared dark brown/ black and focally necrotic. Serial sectioning of the skeletal muscle showed uniform dark brown tissue, with no tumour deposits.

A - G. All of lymph nodes embedded sequentially from one end to the other

A. Portion of involved largest lymph node

B - D. Four lymph nodes

E. Three lymph nodes

F. Two lymph nodes

G. One lymph node

H. Representative skeletal muscle.

2. "MELANOMA RIGHT CHEST WALL". An unorientated piece of fibrofatty tissue 65 x 30 x 30mm, with an overlying ellipse of hair bearing skin 60 x 20mm. Centrally on the skin surface is a circle of purple ink, adjacent to which is a light brown macule 4 x 3mm, the latter of which comes to within 4mm of one long margin. One long margin inked blue, whilst the other long margin inked black. Serial sectioning beneath the purple inked circle reveals a circumscribed dermal and subcutaneous dark brown nodule 9 x 8 x 7mm, coming to within 5mm of the closest long margin. The nodule lies well clear (14mm) of the deep margin.

A - B. All of dermal subcutaneous nodule embedded (B - deep margin has been trimmed).

C - D. All of light brown macule embedded.

MICROSCOPIC REPORT

1. "RIGHT AXILLARY DISSECTION". Sections show metastatic melanoma in fourteen of eighteen lymph nodes (14/18). Abundant finely granular cytoplasmic pigment is seen in the epithelioid cells within the lymph nodes. Large areas of associated necrosis are also seen in several of the nodes. The largest metastasis is 24mm across. There is no extranodal extension. Sections of the skeletal muscle show no significant abnormality.

[page 2 of 2]
Requested by:

Location:
Accession:

HISTOPATHOLOGY REPORT

2. "MELANOMA RIGHT CHEST WALL". The subcutaneous nodule seen macroscopically is a metastatic melanoma which appears completely excised (4mm from the nearest peripheral margin, about 12mm from deep margin). No junctional melanocytic lesion is identified. Tumour cells are epithelioid in appearance with abundant finely granular, cytoplasmic pigment. Although mostly circumscribed, the superficial part of the nodule shows groups of melanoma cells infiltrating dense collagen bundles. The small brown macule is a dysplastic compound naevus, clear of margins by 3mm.

SUMMARY

1. RIGHT AXILLARY LYMPH NODE DISSECTION - METASTATIC MELANOMA IN FOURTEEN OF EIGHTEEN LYMPH NODES (14/18).

/

2. SKIN OF RIGHT CHEST WALL, EXCISION - METASTATIC MELANOMA, EXCISED.

REPORTED BY: Dr

For Malignancy/History		X
Local/Synchronous Primary/No prior		X

Printed:

Page 2 of 2

Source: NCI Genomic Data Commons file 3233d04c-2891-401a-8283-604a4cf7dfdb (TCGA-EE-A17X.B3EC3F2A-D4BF-4BA9-921C-BE4852EFEE8B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).